Somatic mutation profile of tumor specimen TCGA-KS-A4I7-01A (aliquot TCGA-KS-A4I7-01A-11D-A257-08) from TCGA case TCGA-KS-A4I7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 61.3 years (22,398 days).
Specimen TCGA-KS-A4I7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f57c4cf7-0aa2-4347-bf8f-881448571164.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A4I7-11A (Solid Tissue Normal), aliquot TCGA-KS-A4I7-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26f0a96a-e32f-452b-812d-447be6119731

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ERBB4 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99615321; called by muse, mutect2
- NOTCH4 | c.5105C>T p.T1702I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900305; called by muse, mutect2, varscan2
- SPEN | c.5996A>G p.K1999R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV101004967, COSV65368218; called by muse, mutect2
- TAF1 | c.1108G>A p.E370K (on ENST00000373790 / NM_138923.4; = p.E391K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99334262; called by mutect2, varscan2
- ZNF688 | c.717dup p.R240Afs*19 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | catalogued as rs757983438; called by mutect2, pindel, varscan2
